Gene-level copy-number profile of tumor specimen TCGA-AG-A036-01A from TCGA case TCGA-AG-A036, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.7 years (26,206 days).
Specimen TCGA-AG-A036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.a231062a-357c-4103-90d6-e92ab7925466.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A036-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/2d4c12af-e534-4ea8-b35f-93856809effc

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 4,303; copy number 3: 113; copy number 4: 24,702; copy number 5: 8,987; copy number 6: 15,906; copy number 7: 2,753; copy number 9: 1,615; copy number 10: 1,079; copy number 12: 58; copy number 13: 3; copy number 14: 131; copy number 15: 86; copy number 20: 83.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,055 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–65,554,744, 1,213 genes, copy number 10–14 (broad region; genes not listed).
- chr8:41,032,892–145,066,685, 1,615 genes, copy number 9 (broad region; genes not listed).
- chr20:36,561,237–45,811,427, 227 genes, copy number 12–20 (within-gene range 6–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
